Surgical pathology report (de-identified scan), TCGA case TCGA-CV-A45U, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-A45U-01A (Primary Tumor).

[page 1 of 3]
DOB:

Sex: M

Physician:

Received:

Pathologist:

Accession:

Case type: Surgical History

** Case imported from legacy computer system. The format of this report does not match the original case. **
** For cases prior to the section "SPECIMEN" may have been added. **

SUPPLEMENTAL REPORT

DIAGNOSIS:

(D) LEFT HEMIMANDIBULECTOMY:

WELL DIFFERENTIATED SQUAMOUS CARCINOMA INVADING MANDIBULAR BONE,
RESECTION MARGIN FREE OF TUMOR.

ICD-0-3
carcinoma, squamous cell, nos 8070/3
Site: oral cavity c 06.9

Entire report and diagnosis completed by:
Report released by:

W
10/1/12

SIGNATURE:

ENTIRE REPORT ELECTRONICALLY SIGNED BY:

DIAGNOSIS

(A) LEFT NECK, NODES FROM UPPER AND MIDDLE LEVEL 5:

Two lymph nodes, no evidence of metastatic disease.

(B) LEFT SUPRAOMOHYOID LYMPH NODE DISSECTION:

Seven lymph nodes, no evidence of metastatic disease (four
subdigastric, one mid jugular, and one lower jugular).

(C) LEFT ALVEOLAR NERVE:

Peripheral nerve, no evidence of carcinoma.

(D) LEFT HEMIMANDIBULECTOMY:

INVASIVE WELL-DIFFERENTIATED SQUAMOUS CARCINOMA, FOCALLY EXTENDING TO
ANTERIOR MUCOSAL MARGIN, OTHER MARGINS FREE OF TUMOR.

METASTATIC SQUAMOUS CARCINOMA IN 2 OF 4 SUBMAXILLARY LYMPH NODES WITH
EXTRANODAL EXTENSION.

Submandibular gland with mild atrophy, no tumor present.

Skin and subcutaneous tissue of cheek with extensive necrosis, acute
inflammation and foreign body giant cell reaction, no evidence of
carcinoma.

Entire report and diagnosis completed by:
Report released by:

GROSS DESCRIPTION

[page 2 of 3]
DOB:
Physician:

Sex: M

Received:

Pathologist:

Accession:

Case type: Surgical History

(A) NODAL GROUP FROM LEFT UPPER AND MIDDLE LEVEL 5 - Two lymph nodes, one from level 6 (1.2 x 0.8 x 0.4 cm), and one lymph node from level 7 (0.2 x 0.7 x 0.5 cm). Both of the lymph nodes are tan-red and soft to rubbery.

SECTION CODE: A1, one lymph node, bisected from level 6; A2, one lymph node, bisected from level 7.

(B) CONTENTS OF LEFT SUPRAOMOHYOID NECK DISSECTION - A left sided neck dissection (8.0 x 5.5 x 1.5 cm). It is oriented by into levels 3, 4 and 5. The specimen also includes part of the platysma muscle (8.5 x 3.5 x 0.2 cm), and sternomastoid muscle (4.5 x 3.5 x 2.0 cm).

The lymph nodes range in size from 0.2 cm in diameter up to 1.2 x 1.0 x 0.6 cm. The largest lymph node is in level 3. The lymph nodes are pink-tan to red-tan, firm to rubbery.

SECTION CODE: B1-B4, level 3 lymph nodes: B1-B3, 1 lymph node in each cassette; B4, 2 lymph nodes; B5, level 4 lymph nodes (2 lymph nodes): B6, B7, level 5 lymph nodes (B6, 2 lymph nodes; B7, 1 lymph node).

(C) LEFT ALVEOLAR NERVE, CHECK MARGIN OPPOSITE CLAMP - A single segment of nerve (0.9 cm length, 0.2 cm diameter). A clamp is present at one end.

Section Code: C, for frozen section diagnosis, en face, margin of end opposite clamp, remainder of nerve with blue ink at end with clamp.

*FS/DX: PERIPHERAL NERVE, NO TUMOR PRESENT.

(D) LEFT HEMIMANDIBULECTOMY - A left hemimandibulectomy specimen, the ramus is 9.5 cm and the mandible is 9.3 cm. A 3.5 x 2.6 x 1.5 cm unremarkable submandibular gland is present. An 11.0 x 6.0 cm ellipse of tan, hair-bearing skin is present over the lateral aspect of the specimen. A 2.5 x 2.0 cm area of bulging and ulceration is present in the center of the skin.

A 6.3 x 4.2 x 3.0 cm ulcerated tumor overlies the body of the mandible. The mucosal margins range from 0.3 cm to 2.0 cm. The anterior lateral and posterior medial margins appear to come closest to the tumor and the tumor is firm, tan, and focally necrotic and appears grossly to involve the cortical bone. The tumor extends into the adjacent subcutaneous and dermal tissue of the skin. Matted lymph nodes are present near the angle of the mandible. These are grossly involved by partially necrotic tumor. A section of bone will be submitted after decalcification.

SECTION CODE: D1, posterior lateral mucosal margin, en face; D2, posterior lateral mucosal margin en face; D3, central lateral mucosal margin en face; D4, anterior lateral mucosal margin en face; D5, anterior lateral mucosal margin perpendicular (closest margin); D6, anterior lateral mucosal margin en face; D7, anterior medial margin en face; D8, anterior central mucosal margin en face; D9, central medial mucosal margin perpendicular (closest to margin); D10, posterior medial mucosal margin en face; D11, parotid gland; D12, D13, posterior superior skin margin en face; D14, D15, central superior skin margin en face; D16, D17, anterior superior skin margin en face; D18, D19, posterior inferior skin margin en face; D20, D21, central inferior skin margin en face; D22, D23, anterior inferior skin margin en face; D24-D26, posterior mucosa and tumor; D27-D29, central mucosa and tumor; D30, D31, anterior mucosa and tumor; D32, tumor and skin; D33, posterior soft tissue margin en face; D34, anterior soft tissue margin en face; D35, medial soft tissue margin en face; D36, lateral inferior soft tissue margin en face; D37, D38, perpendicular sections including tumor mucosa, skin and dermal bulge; D39, one representative section of one lymph node; D40, representative section of one lymph node; D41, one lymph node.

Page 2 of 3

History Case Pathology Report
File under: Pathology

History Case Pathology

[page 3 of 3]
DOB:
Physician:

Sex: M

Received:

Pathologist

Accession:

Case type: Surgical History

SNOMED CODES
M-80703 T-11180

Source: NCI Genomic Data Commons file 4197dff6-6dad-4ad2-aa78-26f7c3acad65 (TCGA-CV-A45U.1AF4D20D-572C-434F-B235-053B66AAD3FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).